Gene-level copy-number profile of tumor specimen ALCH-B2V0-TTP1-A from ALCHEMIST case ALCH-B2V0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 35.2 years (12,856 days).
Specimen ALCH-B2V0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 876d1b45-4ebc-498e-948a-831eb70c8e63.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2V0-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/45e7bcd3-afc8-4b96-a5e4-c30ffee35472

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 88; copy number 1: 3,979; copy number 2: 53,399; copy number 3: 905; copy number 4: 15; copy number 5: 4; copy number 8: 5; copy number 39: 1; copy number 43: 1.

Homozygous deletions (total copy number 0; autosomes only): 85 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,512,162–1,534,685, 1 gene: ATAD3A.
- chr1:156,687,695–156,691,997, 1 gene: AL590666.3.
- chr4:625,573–770,640, 9 genes (within-gene range 0–2): PDE6B, PDE6B-AS1, AC107464.2, ATP5ME, MYL5, SLC49A3, PCGF3, AC107464.1, AC139887.4.
- chr4:979,073–1,004,564, 2 genes (within-gene range 0–2): SLC26A1, IDUA.
- chr5:659,862–693,352, 2 genes (within-gene range 0–3): TPPP, AC026740.1.
- chr6:42,101,119–42,142,620, 1 gene: C6orf132.
- chr7:5,495,819–5,495,917, 1 gene (within-gene range 0–1): MIR589.
- chr14:104,138,723–104,180,894, 1 gene: KIF26A.
- chr15:25,194,921–25,250,940, 31 genes (within-gene range 0–2): SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:41,825,099–41,899,528, 8 genes (within-gene range 0–2): AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310, AC020659.1.
- chr16:58,496,908–58,497,014, 1 gene (within-gene range 0–2): RNU6-103P.
- chr16:89,818,179–89,871,319, 1 gene: SPIRE2.
- chr16:89,919,165–89,938,761, 3 genes (within-gene range 0–1): AC092143.1, AC092143.2, TUBB3.
- chr17:2,689,386–2,749,504, 7 genes: CLUH, MIR6776, AC005696.1, AC005696.4, CCDC92B, MIR1253, hsa-mir-1253.
- chr17:5,126,740–5,127,010, 1 gene (within-gene range 0–2): AC012146.3.
- chr17:30,702,504–30,702,775, 1 gene: RN7SL316P.
- chr17:30,724,982–30,731,202, 3 genes (within-gene range 0–2): AC127024.7, AC127024.3, AC127024.2.
- chr17:62,679,403–62,684,010, 2 genes (within-gene range 0–1): AC080038.3, RNU6-446P.
- chr18:79,420,836–79,422,780, 1 gene (within-gene range 0–1): AC018445.3.
- chr19:13,116,862–13,158,788, 8 genes (within-gene range 0–2): NACC1, AC005546.1, AC011446.1, STX10, IER2, AC011446.3, AC011446.2, RPL12P42.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:74,650,231–74,760,692, 3 genes, copy number 5: GTF2I, AC211433.1, PHBP15.
- chr11:1,947,278–1,984,522, 1 gene, copy number 39 (within-gene range 2–39): MRPL23.
- chr11:1,991,096–2,001,470, 5 genes, copy number 8: LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr21:43,461,960–43,479,534, 2 genes, copy number 5–43: LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 3,979. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
